Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A0LV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A0LV-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3

Specimens Submitted:

- 1: SP: Left tube and ovary
- 2: SP: Right tube and ovary
- 3: SP: Uterus; total hysterectomy
- 4: SP: Enlarged left external iliac lymph node
- 5: SP: Enlarged left obturator lymph node (
- 6: SP: Enlarged distal left external iliac lymph nodes
- 7: SP: Enlarged right obturator lymph node #2
- 8: SP: Right jackson nobe
- 9: SP: Enlarged left superficial inguinal lymph node
- 10: SP: Enlarged left external iliac lymph node #2
- 11: SP: Left Jackson's lymph node
- 12: SP: Left common iliac lymph node
- 13: SP: Enlarged right common iliac lymph node
- 14: SP: Enlarged right external iliac lymph node
- 15: SP: Enlarged right obturator lymph node

adenocarcinoma, endometrioid, NOS

8380/3

Site: endometrium C54.1

hw
5/1/11

DIAGNOSIS:

1. SP: Fallopian tube and ovary, left; salpingo-oophorectomy:
- Ovary with numerous cystic follicles and stromal hyperplasia.
- Benign fallopian tube with paratubal cysts.
2. SP: Fallopian tube and ovary, right; salpingo-oophorectomy:
- Ovary with numerous cystic follicles and stromal hyperplasia.
- Benign fallopian tube with paratubal cysts.
3. SP: Uterus; total hysterectomy:
- Tumor Type:
- Adenocarcinoma, endometrioid type
- Architectural Grade (For Endometrioid Types only):
- I (<6% solid growth)
- Nuclear Grade (For Endometrioid Types only):
- Grade 2
- FIGO Grade (For Endometrioid Types only):
- Grade 1
- Myometrial Invasion:

** Continued on next page **

[page 2 of 3]
(= < 50%)

Page 2 of 8

Measures 10mm in maximum depth

Myometrium thickness measures 28mm in the area of maximal tumor

invasion

Endocervical Invasion:

Not identified

Lymphovascular invasion:

Not identified

Endometrium:

Exhibits complex hyperplasia with atypia

Myometrium:

Exhibits adenomyosis

-
4. SP: Enlarged left external iliac lymph node; excision:
- One benign lymph node (0/1).
5. SP: Enlarged left obturator lymph node; excision:
- Two benign reactive lymph nodes (0/2).
6. SP: Enlarged distal left external iliac lymph nodes; excision:
- One benign reactive lymph node (0/1).
7. SP: Enlarged right obturator lymph node #2; excision:
- Two benign lymph nodes (0/2).
8. SP: Right jackson node; excision:
- One benign lymph node (0/1).
9. SP: Enlarged left superficial inguinal lymph node; excision:
- One benign reactive lymph node showing reactive follicular hyperplasia (0/1, see note).

Note: Dr. [REDACTED] has reviewed these slides and concurs with the diagnosis.

10. SP: Enlarged left external iliac lymph node #2; excision:
- Two benign reactive lymph nodes (0/2).
11. SP: Left lymph node; excision:
- One benign reactive lymph node (0/1).
12. SP: Left common iliac lymph node; excision:
- One benign lymph node (0/1).
13. SP: Enlarged right common iliac lymph node; excision:
- One benign reactive lymph node (0/1).
14. SP: Enlarged right external iliac lymph node; excision:
- Three benign reactive lymph nodes (0/3).
15. SP: Enlarged right obturator lymph node; excision:
- One benign reactive lymph node (0/1).

** Continued on next page **

[page 3 of 3]
TSS Name/#:

----- Page 3 of 8

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file c167da01-bdeb-48ec-a2c6-891c96101276 (TCGA-AP-A0LV.75767B04-9FDF-4EE9-8DFF-350B60AF281C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).